Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3C8, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3C8-06A (Metastatic).

UUID:SC5C982D-C8DA-4F75-BFF9-12B420DCACB7

DIAGNOS

Patient ID

1CD-0-3

Melanoma, NOS 8720/3

Site: Subcutaneous tissue, scalp
C49.0

hw 10/3/11

(A) SCALP, SKIN ELLIPSE:

MELANOMA METASTATIC TO SUBCUTANEOUS TISSUE, MARGINS FREE

TUMOR SIZE: 45.0 X 40.0 MM

Tumor borders infiltrative

(B) NECK, LEFT POSTERIOR, LYMPHADENECTOMY:

See addendum report.

GROSS DESCRIPTION

(A) SCALP RESECTION, LONG STITCH ANTERIOR, SHORT STITCH RIGHT LATERAL – A skin ellipse/oval measuring 11.5 x 8.5 x 3.5 cm. Centrally, there is a partially ulcerated lesion measuring 4.5 x 4.0 x 3.5 cm. Closest margin to tumor is left-anterior (1.3 mm). There is a similar, separate lesion measuring 1.3 x 1.3 x 1.0 cm, 5.0 mm anterior to the main lesion. The specimen is differentially inked (yellow left, blue right) and submitted as follows. The deep margin is freely moveable and is not attached to the tumor.

SECTION CODE: A1, anterior tip; A2, posterior; A3, right; A4, left (closest margin 1.3 mm from lesion); A5, separate nodule; A6-A14, representative section of tumor including deep margin.

(B) LEFT POSTERIOR NECK DISSECTION – Three pieces of pink-tan fatty tissue 13 x 6.0 x 1.5 cm, 6.5 x 5.0 x 1.5 cm and 6.0 x 3.0 x 0.7 cm. The fatty tissue is dissected for lymph nodes. The largest lymph node is 3.5 x 1.5 x 1.0 cm with a tan-brown fleshy cut surface. Representative sections from grossly involved lymph nodes are submitted for tissue bank.

SECTION CODE: B1, one lymph node; B2, B3, one lymph node each; B4, three possible lymph nodes; B5, three possible lymph nodes; B6, one lymph node; B7, four possible lymph nodes; B8, four possible lymph nodes; B9, five possible nodes; B10, five possible lymph nodes; B11, five possible lymph nodes; B12, six possible lymph nodes.

CLINICAL HISTORY

None given.

SNOMED CODES

M-87206 M-00110 T-C4000

Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration.*

Entire report and diagnosis completed by:

These tests have not been

Source: NCI Genomic Data Commons file e72e88dc-9168-4aa0-b5c8-3560e290051e (TCGA-D3-A3C8.5C5C982D-CBDA-4F75-BFF9-12B420DCACB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).